Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A669, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A669-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation / Department of Pathology

ICD-0-3

Oligodendroglioma, anaplastic
9451/3

Site: *Brain NOS C71.9*

66CF Brain, supratentorial NOS

9451/3 C71.0

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

- | | |
|------------------------------------|----------------------------|
| A. Brain tumor | A. Frozen Section Charge |
| B. Brain tumor | B. Glial Fibrill. Acid Prt |
| B. 1P19q Malignant Glioma Analysis | B. 1P19q |
| Malignant Glioma Analysis, add | B. KI-67, |
| Nuclear Antigen, Mib1 | |

CLINICAL HISTORY: year old male with tremor in bilateral upper extremities. MRI revealed enhancing cystic lesion left parietal occipital region.

GROSS DESCRIPTION: Received the following specimen in the Department of Pathology, labeled with the patient's name and hospital #:

- A. Brain tumor
- B. Brain tumor

The specimen is received fresh and consists of a 0.5 x 0.5 x 0.4 cm portion of beige to pink-tan soft tissue. A representative portion is submitted for frozen section. Frozen section diagnosis is, "Malignant glioma," . The frozen tissue is submitted in cassette ESA1 and the remaining tissue is submitted in cassette A2.

The specimen is received fresh and consists of a 5.5 x 5.0 x 2.0 cm portion of homogeneous beige to pink-tan soft tissue. A small amount of blood clot is attached. The tissue is partially cystic with wall ranging from 0.2 up to 1.0 cm. A small amount of apparent white matter is focally visible on outer surface of the specimen. Sectioning reveals areas of golden brown to yellow discoloration. A portion of the tissue is submitted for tumor bank per patient request. The remaining tissue is submitted in cassettes B1-B5.

DIAGNOSIS:

- A. "Brain tumor":
Anaplastic oligodendroglioma
- B. "Brain tumor":

Anaplastic oligodendroglioma (see comment)

COMMENT: This neoplasm is highly cellular and presents an overall uniform histologic pattern. In specimen "A2", a clear oligodendroglial appearance is apparent with histologic uniformity, distinct cell borders, perinuclear haloes, and background chicken wire vasculature. Cytologic uniformity, distinct cell borders, and chicken wire vasculature are maintained in specimen "B" although there is an abundance of "microgemistocytic" forms with less cells having perinuclear haloes. The latter cells are strongly immunoreactive for GFAP. There is focal

[page 2 of 2]
vascular endothelial proliferation and brisk mitotic activity. The Ki67 labeling index by immunohistochemistry is 15-20%. The results of chromosomes 1p and 19q analysis by FISH will be added to this report as an addendum.

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Note: Test systems have been developed and their performance characteristics determined by [REDACTED] Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Pathologist [REDACTED]

ADDENDUM:

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) WAS PERFORMED ON REPRESENTATIVE PARAFFIN-EMBEDDED TUMOR TISSUE. IN THIS CASE, DELETIONS OF CHROMOSOME 1P WERE IDENTIFIED BUT NO DELETIONS OF CHROMOSOME 19Q WERE DETECTED. RECENT CLINICAL STUDIES HAVE SUGGESTED THAT LOSSES OF CHROMOSOME 1P AND/OR 19Q IN OLIGODENDROGLIAL BRAIN TUMORS MAY BE ASSOCIATED WITH ENHANCED RESPONSE TO CHEMOTHERAPY (REFS 1-5).

REFERENCES:

1. CAIRNCROSS JG, UEKI K, ZLATESCU MC ET AL. SPECIFIC GENETIC PREDICTORS OF CHEMOTHERAPEUTIC RESPONSE AND SURVIVAL IN PATIENTS WITH ANAPLASTIC OLIGODENDROGLIOMAS. J NATL CANCER INST 90:1473-1479, 1998.
2. SMITH JS, PERRY A, BORELL TJ, ET AL. ALTERATIONS OF CHROMOSOME ARMS 1P AND 19Q AS PREDICTORS OF SURVIVAL IN OLIGODENDROGLIOMAS, ASTROCYTOMAS, AND MIXED OLIGOASTROCYTOMAS. J CLIN ONCOL 18:636-45, 2000.
3. INO Y, BETENSKY RA, ZLATESCU MC, ET AL. MOLECULAR SUBTYPES OF ANAPLASTIC OLIGODENDROGLIOMA: IMPLICATIONS FOR PATIENT MANAGEMENT AT DIAGNOSIS. CLIN CANCER RES 7:839-45, 2001.
4. PERRY A, FULLER CE, BANERJEE R, BRAT DJ, SCHEITHAUER BW. ANCILLARY FISH ANALYSIS FOR 1P AND 19Q STATUS: PRELIMINARY OBSERVATIONS IN 287 GLIOMAS AND OLIGODENDROGLIOMA MIMICS. FRONT BIOSCI 8:A1-9, 2003.
5. MCDONALD JM, SEE SJ TREMONT IW, ET AL. THE PROGNOSTIC IMPACT OF HISTOLOGY AND 1P/19Q STATUS IN ANAPLASTIC OLIGODENDROGLIAL TUMORS.

Pathologist [REDACTED]

COMMENT:

THE HISTOLOGIC GRADE OF THIS TUMOR IS ADDED BELOW:
DIAGNOSIS: ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III)

Pathologist [REDACTED]

ADDENDUM:

THE HISTOLOGIC GRADE OF THIS TUMOR IS: WHO GRADE III OF IV.

Pathologist [REDACTED]

Source: NCI Genomic Data Commons file 9994db96-a5fd-4a4d-aa4b-83ec79d17460 (TCGA-DH-A669.4CE3DBDD-6A16-46B2-A8AA-80A0D8702116.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).